Somatic mutation profile of tumor specimen MP2PRT-PATUEF-TMP1-A (aliquot MP2PRT-PATUEF-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATUEF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,370 days).
Specimen MP2PRT-PATUEF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efe583a1-21fd-4233-9a63-0629f194ca9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATUEF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATUEF-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e497ccb2-a9d9-44e7-8b78-c5a2ad13046c

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIVM-ERCC5 | c.4315G>A p.D1439N | Missense Mutation (SNP) | VAF 182/354 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748797643, COSV63245483; called by muse, mutect2, varscan2
- CUX2 | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 295/699 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.367); catalogued as rs760670696, COSV55639376; called by muse, mutect2, varscan2
- KIAA1217 | c.2578G>A p.G860S | Missense Mutation (SNP) | VAF 520/766 reads (68%) | SIFT tolerated (0.43); PolyPhen benign (0.191); catalogued as rs146210961; called by muse, mutect2, varscan2
- KIF7 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs768030553; called by muse, mutect2, varscan2
- KRAS | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 157/342 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55561078, COSV55580549, COSV55715402; called by muse, mutect2, varscan2
- OSBPL5 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 156/409 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs141647338; called by muse, mutect2, varscan2
- PPP2R2B | c.848C>T p.S283L (on ENST00000394409; = p.S349L on NM_181674.2) | Missense Mutation (SNP) | VAF 180/381 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770649547, COSV60761342; called by muse, mutect2, varscan2
- TNC | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 193/417 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs142899177; called by muse, mutect2, varscan2
- ADAMTS5 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 205/698 reads (29%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- GREB1L | c.1563G>T p.L521F | Missense Mutation (SNP) | VAF 192/430 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- B3GNT9 | c.1134G>A p.L378= | Silent (SNP) | VAF 173/417 reads (41%) | called by muse, mutect2, varscan2
- BPIFA2 | c.588C>T p.F196= | Silent (SNP) | VAF 132/148 reads (89%) | catalogued as rs528886764, COSV53612060; called by muse, mutect2, varscan2
- CNOT4 | c.1995G>A p.P665= (on ENST00000541284 / NM_001190850.1; = p.P591= on NM_013316.4) | Silent (SNP) | VAF 225/500 reads (45%) | catalogued as rs374538900; called by muse, mutect2, varscan2
- TTN | c.3021G>A p.A1007= (on ENST00000591111; = p.A961= on NM_003319.4) | Silent (SNP) | VAF 160/383 reads (42%) | catalogued as rs147603843; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
